Gene-level copy-number profile of tumor specimen TCGA-FV-A23B-01A from TCGA case TCGA-FV-A23B, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Age at diagnosis: 70.6 years (25,788 days).
Specimen TCGA-FV-A23B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.b35c7cbe-9e12-48e2-b219-da1221c7ebfc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FV-A23B-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a69824a8-ff8f-4e33-b84f-17b67cabcc7b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,294; copy number 2: 45,285; copy number 3: 5,453; copy number 4: 431; copy number 5: 297; copy number 6: 51; copy number 7: 1; copy number 8: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FV-A23B-01A-11D-A16U-01): tumor purity 0.86, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 356 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:44,809,317–45,377,953, 6 genes, copy number 8: SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586.
- chr6:45,421,079–45,422,005, 1 gene, copy number 8: AL096865.1.
- chr6:55,327,469–55,402,493, 1 gene, copy number 7 (within-gene range 2–7): GFRAL.
- chr13:96,090,839–96,839,562, 1 gene, copy number 5 (within-gene range 3–5): HS6ST3.
- chr13:96,427,229–101,059,286, 90 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:108,596,152–111,672,608, 51 genes, copy number 6 (within-gene range 3–6): MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, AL390755.3, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1, TEX29, AL359649.1, LINC02337.
- chr15:97,876,289–101,933,350, 110 genes, copy number 5 (broad region; genes not listed).
- chr17:31,583,162–34,363,233, 90 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr17:51,336,646–52,899,588, 6 genes, copy number 5 (within-gene range 2–5): LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089.

Autosomal genes at a single copy (total copy number 1): 8,294. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
